Somatic mutation profile of tumor specimen TCGA-KR-A7K7-01A (aliquot TCGA-KR-A7K7-01A-11D-A33K-10) from TCGA case TCGA-KR-A7K7, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G1; Age at diagnosis: 61.8 years (22,587 days).
Specimen TCGA-KR-A7K7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) da215bf4-08ff-40a7-815c-eb136252ecee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KR-A7K7-10A (Blood Derived Normal), aliquot TCGA-KR-A7K7-10A-01D-A33K-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f9fc2bc9-2e7b-4e9a-8d2e-eadd01129c3b

The open-access MAF lists 67 somatic variants for this specimen: 53 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 44, Silent 14, Nonsense Mutation 5, Frame Shift Del 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2995C>T p.Q999* | Nonsense Mutation (SNP) | VAF 47/103 reads (46%) | catalogued as rs75239284, CM994279, COSV57331655; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADNP2 | c.2915C>A p.S972Y | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.465); catalogued as COSV51537031; called by muse, mutect2, varscan2
- ANKRD12 | c.408G>C p.Q136H | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV50820422; called by muse, mutect2, varscan2
- ARHGAP39 | c.3172G>C p.E1058Q (on ENST00000276826 / NM_001308208.2; = p.E1089Q on NM_025251.2) | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV52768024; called by muse, mutect2, varscan2
- BSN | c.6741T>G p.I2247M | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.564); catalogued as COSV56514315; called by muse, mutect2, varscan2
- CDSN | c.662A>G p.D221G | Missense Mutation (SNP) | VAF 65/121 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV52537503; called by muse, mutect2, varscan2
- COL19A1 | c.2776G>A p.G926R | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59568030; called by muse, mutect2, varscan2
- COL4A6 | c.2258T>G p.I753S | Missense Mutation (SNP) | VAF 161/352 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57860976; called by muse, mutect2, varscan2
- COL5A3 | c.3969A>T p.R1323S | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as COSV53407655; called by muse, mutect2, varscan2
- CPD | c.2615G>T p.R872L | Missense Mutation (SNP) | VAF 55/198 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.303); catalogued as rs766518499, COSV56711389, COSV56711830; called by muse, mutect2, varscan2
- CSMD3 | c.7149dup p.V2384Cfs*22 (on ENST00000297405 / NM_001363185.1; = p.V2280Cfs*22 on NM_052900.3) | Frame Shift Ins (INS) | VAF 20/190 reads (11%) | catalogued as rs1230860045; called by mutect2, pindel, varscan2
- CTU2 | c.162C>G p.F54L | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs770694267, COSV56378389; called by muse, mutect2, varscan2
- DPP7 | c.213C>G p.I71M | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs779091380, COSV65371049; called by muse, mutect2, varscan2
- ERF | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1479656985, COSV55895216; called by muse, mutect2, varscan2
- FREM2 | c.2815G>T p.E939* | Nonsense Mutation (SNP) | VAF 14/71 reads (20%) | catalogued as COSV54831335; called by muse, mutect2, varscan2
- HDDC3 | c.209C>T p.T70I | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs921011364, COSV57745773; called by muse, mutect2, varscan2
- HEG1 | c.2849C>T p.P950L | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV60760192; called by muse, mutect2, varscan2
- HIPK1 | c.111T>A p.S37R | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0.207); catalogued as COSV65782959, COSV65783635; called by muse, mutect2, varscan2
- IRX6 | c.774C>G p.D258E | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as COSV51859543; called by muse, mutect2, varscan2
- KCNMA1 | c.308T>A p.F103Y | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as COSV54234407; called by muse, mutect2, varscan2
- MAP4 | c.995A>C p.K332T | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV64237063; called by muse, mutect2, varscan2
- MAP7D1 | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764389319, COSV60215385; called by muse, mutect2
- MAPK10 | c.839T>A p.F280Y (on ENST00000359221 / NM_001351625.2; = p.F318Y on NM_002753.5) | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60377886; called by muse, mutect2, varscan2
- MAVS | c.802G>T p.E268* | Nonsense Mutation (SNP) | VAF 20/52 reads (38%) | catalogued as COSV63926572, COSV99050295; called by muse, mutect2, varscan2
- MBOAT1 | c.780G>T p.K260N | Missense Mutation (SNP) | VAF 71/169 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.557); catalogued as COSV61124028; called by muse, mutect2, varscan2
- MGAT2 | c.1044G>A p.W348* | Nonsense Mutation (SNP) | VAF 21/86 reads (24%) | catalogued as COSV53565739; called by muse, mutect2, varscan2
- MTERF2 | c.277G>C p.A93P | Missense Mutation (SNP) | VAF 42/78 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.399); catalogued as COSV53527136; called by muse, mutect2, varscan2
- MYO1A | c.1570A>T p.N524Y | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55652409; called by muse, mutect2, varscan2
- NEU3 | c.665G>A p.C222Y | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV53635920; called by muse, mutect2, varscan2
- NEU3 | c.938A>G p.Q313R | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV53635937; called by muse, mutect2, varscan2
- OR51G2 | c.782T>C p.I261T | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58992124; called by muse, mutect2, varscan2
- PCDHGA5 | c.1582C>A p.L528I | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.461); catalogued as COSV53914297; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.2161G>A p.V721M | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.006); catalogued as rs368706939; called by muse, mutect2, varscan2
- PRDM2 | c.798G>T p.L266F | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.054); catalogued as COSV52443945; called by muse, mutect2
- SCN7A | c.3308A>C p.N1103T | Missense Mutation (SNP) | VAF 124/297 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as COSV69269822; called by muse, varscan2
- SETBP1 | c.4771G>C p.E1591Q | Missense Mutation (SNP) | VAF 52/195 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV56315715; called by muse, mutect2, varscan2
- SFXN5 | c.783G>A p.M261I | Missense Mutation (SNP) | VAF 66/239 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as rs757166628, COSV55585360; called by muse, mutect2, varscan2
- SH3KBP1 | c.1784G>A p.G595E | Missense Mutation (SNP) | VAF 45/219 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV65646343; called by muse, mutect2, varscan2
- SLC2A10 | c.929C>G p.S310C | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.073); catalogued as COSV63713584, COSV63713909, COSV63714495; called by muse, mutect2, varscan2
- SLC6A19 | c.1735C>A p.P579T | Missense Mutation (SNP) | VAF 58/119 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57250015; called by muse, mutect2, varscan2
- SMYD1 | c.139C>T p.L47F | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0.062); catalogued as COSV101352527, COSV70224640; called by muse, mutect2, varscan2
- SORCS3 | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.136); catalogued as rs550554404, COSV63804214; called by muse, mutect2, varscan2
- TIMELESS | c.1261A>T p.M421L | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.485); catalogued as COSV57509732; called by muse, mutect2, varscan2
- TNFRSF11A | c.1417G>A p.A473T | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.72); PolyPhen benign (0.013); catalogued as rs777022699, COSV54022316; called by muse, mutect2, varscan2
- TRIP12 | c.2765G>A p.R922K | Missense Mutation (SNP) | VAF 65/155 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.815); catalogued as COSV52260577; called by muse, mutect2, varscan2
- UBR2 | c.2037T>G p.Y679* | Nonsense Mutation (SNP) | VAF 25/53 reads (47%) | catalogued as COSV65749256; called by muse, mutect2, varscan2
- WSCD1 | c.1423G>A p.V475I | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.644); catalogued as rs191802540; called by muse, mutect2, varscan2
- ZFP28 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs1358355574, COSV100019272, COSV56734974; called by muse, mutect2, varscan2
- ZNF470 | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 45/83 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0.165); catalogued as COSV57967993, COSV57971154; called by muse, mutect2, varscan2
- ZNF567 | c.137G>A p.G46E (on ENST00000536254 / NM_001322913.1; = p.G15E on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/90 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62444560; called by muse, mutect2, varscan2
- EFCAB3 | c.125del p.K42Rfs*3 | Frame Shift Del (DEL) | VAF 34/94 reads (36%) | called by mutect2, pindel, varscan2
- NCOA5 | c.602del p.S201Lfs*2 | Frame Shift Del (DEL) | VAF 62/169 reads (37%) | called by mutect2, pindel, varscan2
- SREBF1 | c.314_318del p.T105Ifs*226 | Frame Shift Del (DEL) | VAF 22/48 reads (46%) | called by mutect2, pindel, varscan2
- CELF1 | c.45T>A p.A15= | Silent (SNP) | VAF 30/138 reads (22%) | catalogued as COSV60110509; called by muse, mutect2, varscan2
- FBXO43 | c.1302A>G p.L434= | Silent (SNP) | VAF 39/341 reads (11%) | catalogued as rs947225821, COSV71053534; called by muse, mutect2, varscan2
- KCNV1 | c.1029C>T p.Y343= | Silent (SNP) | VAF 21/104 reads (20%) | catalogued as rs754470123, COSV52085068; called by muse, mutect2, varscan2
- KSR2 | c.525G>A p.T175= | Silent (SNP) | VAF 30/74 reads (41%) | catalogued as rs751706259, COSV60369016; called by muse, mutect2
- OR10J1 | c.929G>A p.*310= | Silent (SNP) | VAF 26/43 reads (60%) | catalogued as COSV71128383; called by muse, mutect2, varscan2
- RARS2 | c.1467T>C p.C489= | Silent (SNP) | VAF 20/118 reads (17%) | catalogued as COSV65760075; called by muse, mutect2, varscan2
- RBP3 | c.1617G>A p.L539= | Silent (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2
- RTN4RL1 | c.729G>A p.P243= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as rs1388490270, COSV100486902; called by muse, mutect2
- TLN1 | c.6375G>C p.V2125= | Silent (SNP) | VAF 31/75 reads (41%) | catalogued as COSV59205102; called by muse, mutect2, varscan2
- TNRC18 | c.2475A>G p.P825= | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as rs754690082, COSV68163632; called by muse, mutect2
- TRIL | c.60G>A p.P20= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV59866701; called by muse, mutect2, varscan2
- TSPOAP1 | c.1279C>T p.L427= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV52105674; called by muse, mutect2
- UBQLN1 | c.393A>G p.S131= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV57407020; called by mutect2, varscan2
- ZBTB20 | c.570G>A p.T190= (on ENST00000474710 / NM_001164342.2; = p.T117= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs752505202, COSV61845221; called by muse, mutect2, varscan2
